Somatic mutation profile of tumor specimen MMRF_1839_1_BM_CD138pos (aliquot MMRF_1839_1_BM_CD138pos_T1_KBS5U_L06424) from MMRF case MMRF_1839, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,384 days).
Specimen MMRF_1839_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47007c44-970e-4d0a-b1ed-3811667a19b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1839_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1839_1_PB_Whole_C3_KBS5U_L06470; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e111d59e-9749-4f11-aa45-d921b6df1535

The open-access MAF lists 139 somatic variants for this specimen: 51 protein-altering or splice-affecting, 20 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 42, Missense Mutation 42, Silent 20, Intron 14, 5'UTR 7, Nonsense Mutation 4, 3'Flank 3, Frame Shift Del 2, 5'Flank 2, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B9D1 | c.434C>G p.T145R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as CM1511904; called by muse, mutect2, varscan2
- BAHCC1 | c.6688C>T p.R2230W | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782041539; called by muse, varscan2
- CCDC149 | c.1127G>C p.R376T (on ENST00000635206 / NM_001330643.2; = p.R365T on NM_173463.5) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as rs574948043; called by muse, mutect2, varscan2
- CDH4 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs749580573, COSV64645529; called by muse, mutect2, varscan2
- COL12A1 | c.5873C>A p.P1958Q | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV59411771; called by muse, mutect2, varscan2
- CUX2 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99920865; called by muse, mutect2, varscan2
- DRP2 | c.2829T>A p.S943R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV67871287; called by muse, mutect2, varscan2
- EBI3 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1301581972; called by muse, mutect2
- HOXD4 | c.391del p.A131Pfs*7 | Frame Shift Del (DEL) | VAF 51/122 reads (42%) | catalogued as COSV60459886; called by mutect2, pindel, varscan2
- IGLV3-1 | c.133A>T p.K45* | Nonsense Mutation (SNP) | VAF 53/97 reads (55%) | catalogued as rs187892119; called by muse, mutect2, varscan2
- NAV1 | c.2674A>G p.M892V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs755843708; called by muse, mutect2, varscan2
- NKAIN3 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60657138, COSV60692067; called by muse, mutect2, varscan2
- PELP1 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); catalogued as rs759715894; called by muse, mutect2
- PIGQ | c.2044G>A p.V682M | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); catalogued as rs753328638; called by muse, mutect2, varscan2
- PROSER2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186708228; called by muse, mutect2, varscan2
- SAMD9L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1562797171; called by muse, mutect2, varscan2
- SDK1 | c.4528C>T p.R1510W | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765428605, COSV67376333; called by muse, mutect2, varscan2
- SELP | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.138); catalogued as rs1231276533; called by muse, mutect2
- SI | c.3373G>A p.D1125N | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs1268825082, COSV52302554; called by muse, mutect2
- SLC9A4 | c.2333C>A p.T778K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV54837198; called by muse, mutect2, varscan2
- TP53 | c.392A>C p.N131T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; called by muse, mutect2, varscan2
- ARHGEF12 | c.33-1G>T p.X11_splice | Splice Site (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- COL19A1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPEB4 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DOCK1 | c.5329C>T p.L1777F | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- DUSP9 | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- DYNC2H1 | c.8654G>A p.S2885N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPC5 | c.738A>T p.K246N | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- H1-4 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- H3C3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 95/97 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LNPK | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LRP1B | c.8978G>A p.C2993Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MASTL | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MMRN1 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); called by muse, mutect2
- NET1 | c.1778A>C p.E593A (on ENST00000355029 / NM_001047160.3; = p.E539A on NM_005863.5) | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NKX2-1 | c.206A>C p.H69P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- NRAP | c.4861G>T p.D1621Y (on ENST00000359988 / NM_001322945.2; = p.D1586Y on NM_006175.4) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- NSMF | c.797T>G p.L266R (on ENST00000371475 / NM_001130969.3; = p.L264R on NM_015537.4) | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- OR2A1 | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by mutect2, varscan2
- PCDHA4 | c.2097C>A p.Y699* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- PLOD3 | c.1995_1996insT p.P666Sfs*22 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- PLPPR4 | c.134A>C p.Q45P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLG | c.1413C>G p.C471W | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- POLR1A | c.4863del p.I1621Mfs*37 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- RICTOR | c.4685C>A p.P1562H | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCAD1 | c.2992G>T p.E998* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- TEP1 | c.5761C>T p.H1921Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TEX45 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2
- TMC8 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF197 | c.1140T>A p.N380K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2
- ATP6V0E1 | c.45G>A p.V15= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- CPEB4 | c.613C>T p.L205= | Silent (SNP) | VAF 8/229 reads (3%) | called by muse, mutect2
- CTNNA2 | c.822C>A p.G274= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as rs772578256; called by muse, mutect2, varscan2
- EML4 | c.660C>T p.I220= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- GRWD1 | c.1272G>A p.P424= | Silent (SNP) | VAF 109/219 reads (50%) | catalogued as rs375593627; called by muse, mutect2, varscan2
- IGLV4-3 | c.150C>T p.Y50= | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as rs1260414622; called by muse, mutect2, varscan2
- KIF5A | c.1614G>A p.E538= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- KLK11 | c.843C>T p.N281= (on ENST00000594768 / NM_144947.3; = p.N249= on NM_006853.3) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs749451322; called by muse, mutect2, varscan2
- PALMD | c.1653C>A p.I551= | Silent (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- PRDM6 | c.738C>G p.R246= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- PRR12 | c.996G>A p.R332= (on ENST00000615927; = p.R1153= on NM_020719.3) | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- PTCHD3 | c.81G>T p.P27= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs760062372, COSV101438833; called by muse, mutect2, varscan2
- PWWP3B | c.66A>G p.R22= | Silent (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- SCN5A | c.2013C>T p.S671= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs751050999, COSV61135167; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SEMA5A | c.1824C>T p.S608= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV101228303; called by mutect2, varscan2
- ST6GALNAC4 | c.282C>A p.I94= | Silent (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- SULT6B1 | c.390G>A p.E130= (on ENST00000535679 / NM_001367551.1; = p.E92= on NM_001032377.2) | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs760222223; called by muse, mutect2, varscan2
- TIAM1 | c.1134G>A p.A378= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as rs374340137; called by muse, mutect2, varscan2
- TTC28 | c.972C>T p.Y324= | Silent (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- VIRMA | c.2481T>G p.T827= | Silent (SNP) | VAF 67/131 reads (51%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+8162G>A | Intron (SNP) | VAF 54/140 reads (39%) | catalogued as rs553137878, COSV52553228; called by muse, mutect2, varscan2
- ADD3 | c.*1800C>T | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501333 T>G | 5'Flank (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- AP001993.1 | chr11:127100092 T>C | 3'Flank (SNP) | VAF 45/68 reads (66%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915242 T>G | 5'Flank (SNP) | VAF 72/150 reads (48%) | called by muse, mutect2, varscan2
- ATP5MD | c.-1C>G | 5'UTR (SNP) | VAF 68/207 reads (33%) | called by muse, mutect2, varscan2
- BDKRB2 | c.75-946G>A | Intron (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- BNIP2 | c.*2386C>T | 3'UTR (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- BRSK2 | c.1939+277del | Intron (DEL) | VAF 30/76 reads (39%) | catalogued as rs751872197, COSV100373197; called by mutect2, varscan2
- CACNG8 | c.*4683G>C | 3'UTR (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- CBLN4 | c.*699T>G | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- CCDC50 | c.*3737T>A | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CLCN6 | c.*880A>G | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- CLDN18 | c.*538G>C | 3'UTR (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- CROCCP2 | n.495+10056G>T | Intron (SNP) | VAF 26/146 reads (18%) | called by muse, mutect2
- CXCL12 | c.266+837C>A | Intron (SNP) | VAF 34/77 reads (44%) | catalogued as COSV100639022; called by muse, mutect2, varscan2
- CYP26B1 | c.*535C>T | 3'UTR (SNP) | VAF 23/53 reads (43%) | catalogued as rs919816973; called by muse, mutect2, varscan2
- DCAF4L2 | c.*1728G>T | 3'UTR (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- DCLK1 | c.*2423G>T | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- DDX52 | c.*3350G>C | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- DUSP2 | c.511-50C>T | Intron (SNP) | VAF 18/28 reads (64%) | catalogued as rs952192391; called by muse, mutect2, varscan2
- EGR1 | c.-61G>A | 5'UTR (SNP) | VAF 17/37 reads (46%) | catalogued as COSV53517796; called by muse, mutect2, varscan2
- GABRA6 | c.*349G>T | 3'UTR (SNP) | VAF 17/50 reads (34%) | catalogued as rs531661468; called by muse, mutect2, varscan2
- GASK1B | c.*1041G>A | 3'UTR (SNP) | VAF 21/57 reads (37%) | catalogued as rs559262646; called by muse, mutect2, varscan2
- GIT1 | c.*189G>C | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- GNG12 | c.*3219T>C | 3'UTR (SNP) | VAF 43/61 reads (70%) | called by muse, mutect2, varscan2
- HAPLN2 | c.*189G>C | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- IFNE | c.*98_*99dup | 3'UTR (INS) | VAF 24/50 reads (48%) | catalogued as rs1489487285; called by mutect2, varscan2
- IGKV4-1 | c.-101T>C | 5'UTR (SNP) | VAF 22/22 reads (100%) | called by muse, varscan2
- JAM3 | c.*315C>A | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- MESD | c.*1939G>A | 3'UTR (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- MTX3 | c.*32G>A | 3'UTR (SNP) | VAF 36/131 reads (27%) | catalogued as COSV101560472; called by muse, mutect2, varscan2
- NACA | c.71-1342del | Intron (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- NACC2 | c.*1424G>A | 3'UTR (SNP) | VAF 64/174 reads (37%) | called by muse, mutect2, varscan2
- NAV3 | c.*1059G>T | 3'UTR (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- NFE2L3 | c.*34T>A | 3'UTR (SNP) | VAF 32/158 reads (20%) | called by muse, mutect2, varscan2
- NPAT | c.*179A>T | 3'UTR (SNP) | VAF 83/130 reads (64%) | called by muse, mutect2, varscan2
- NPC1 | c.-31G>T | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+1245C>T | Intron (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- NUP214 | c.*832C>T | 3'UTR (SNP) | VAF 12/47 reads (26%) | catalogued as rs1427702895; called by muse, mutect2, varscan2
- NXF3 | c.29-3870T>C | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- OASL | c.1047+29G>A | Intron (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- OGDH | c.*309C>T | 3'UTR (SNP) | VAF 12/186 reads (6%) | catalogued as rs1377385695; called by muse, mutect2
- OLFM3 | chr1:101803185 A>C | 3'Flank (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- OR2C3 | c.*809C>T | 3'UTR (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- PCSK9 | c.524-1220G>A | Intron (SNP) | VAF 18/25 reads (72%) | catalogued as rs1379832602; called by muse, mutect2, varscan2
- POM121L12 | c.*47C>G | 3'UTR (SNP) | VAF 74/250 reads (30%) | catalogued as COSV101374896; called by muse, mutect2, varscan2
- PRKAA1 | c.*1337G>T | 3'UTR (SNP) | VAF 57/151 reads (38%) | called by muse, mutect2, varscan2
- RAI14 | c.*77A>T | 3'UTR (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- RBM5 | c.*86A>C | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2
- REV3L | c.-342+87C>T | Intron (SNP) | VAF 24/24 reads (100%) | catalogued as rs1184446526; called by muse, mutect2, varscan2
- RPAIN | c.-8A>T | 5'UTR (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- RPS23 | c.*2226T>C | 3'UTR (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- SLC12A6 | c.*8T>A | 3'UTR (SNP) | VAF 118/335 reads (35%) | called by muse, mutect2, varscan2
- SLC25A21 | c.-40C>T | 5'UTR (SNP) | VAF 26/114 reads (23%) | catalogued as rs1281167490; called by muse, mutect2, varscan2
- SLC38A4 | c.*516C>T | 3'UTR (SNP) | VAF 48/49 reads (98%) | called by muse, mutect2, varscan2
- SLC39A14 | c.*27G>A | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- SPAG8 | c.*388C>T | 3'UTR (SNP) | VAF 23/460 reads (5%) | called by muse, mutect2
- STX18 | chr4:4415952 G>A | 3'Flank (SNP) | VAF 40/74 reads (54%) | catalogued as rs763297381; called by muse, mutect2, varscan2
- TAB3 | c.*3793G>A | 3'UTR (SNP) | VAF 37/72 reads (51%) | catalogued as COSV99915960; called by muse, mutect2, varscan2
- TBC1D30 | c.644-3083C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- TGFB2 | c.-383C>A | 5'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- TIAM2 | c.2361+3456C>T | Intron (SNP) | VAF 42/109 reads (39%) | catalogued as rs1209874953; called by muse, mutect2, varscan2
- TMEM19 | c.*1188T>A | 3'UTR (SNP) | VAF 55/56 reads (98%) | called by muse, mutect2, varscan2
- TOR4A | c.*313A>G | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- TRIM38 | c.*307C>T | 3'UTR (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- UBASH3B | c.*2921T>C | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- UGT3A1 | c.*2386A>G | 3'UTR (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
